Gene-level copy-number profile of tumor specimen HCM-CSHL-0186-C25-01A from HCMI case HCM-CSHL-0186-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 74.2 years (27,102 days).
Specimen HCM-CSHL-0186-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2cc332c-2627-4e3f-8aa6-71d1fd907587.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0186-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/6a8cda93-231f-48c3-a6fd-23a9732ecb21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 12,549; copy number 2: 42,164; copy number 3: 4,120; copy number 4: 22; copy number 5: 40.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,548,564–49,589,529, 7 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr15:21,293,653–21,325,241, 3 genes (within-gene range 0–2): AC068446.1, AC068446.2, RNU6-1235P.
- chr15:21,843,750–21,951,323, 6 genes: MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3.
- chr15:22,056,709–22,057,638, 1 gene (within-gene range 0–1): OR4H6P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 40 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:28,378,955–29,142,934, 37 genes, copy number 5: ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, GPX6, GPX5, ZBED9, AL049543.1, AL121932.1, AL121932.2, LINC00533, RPSAP2, NOP56P1, AL662890.1, LINC01623, RPL13P, ZNF90P2, HCG14, TRIM27, RNU6-930P, LINC01556, KRT18P1, RN7SL471P, HCG15, AL662791.1, ZNF311, OR2AD1P, AL662791.2, OR2W1, OR2P1P, SAR1AP1, OR2B3, OR2J1, OR2J3, AL645937.2, AL645937.1.
- chr18:13,151,637–13,216,367, 3 genes, copy number 5: AP001357.1, AP001198.2, AP001198.1.

Autosomal genes at a single copy (total copy number 1): 9,693. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
